Somatic mutation profile of tumor specimen TCGA-B6-A0IM-01A (aliquot TCGA-B6-A0IM-01A-11W-A050-09) from TCGA case TCGA-B6-A0IM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.4 years (27,557 days).
Specimen TCGA-B6-A0IM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 538383ae-c722-44ae-bb58-28a0fd9bb88f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IM-10A (Blood Derived Normal), aliquot TCGA-B6-A0IM-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33144fac-ed5d-42e6-ba5e-bfa38d2b0661

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 16, Silent 8, Splice Site 4, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.3218A>T p.D1073V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV99500668; called by muse, mutect2
- CELSR1 | c.5412+1G>T p.X1804_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV53087755; called by muse, mutect2, varscan2
- EFHB | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs536838707, COSV55546976; called by muse, mutect2, varscan2
- GLI3 | c.2308G>C p.A770P | Missense Mutation (SNP) | VAF 155/297 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67887363; called by muse, mutect2, varscan2
- GPS2 | c.397+1del p.X133_splice | Splice Site (DEL) | VAF 49/99 reads (49%) | catalogued as COSV59752950; called by mutect2, pindel, varscan2
- KCNH1 | c.2123G>A p.R708Q (on ENST00000271751 / NM_172362.3; = p.R681Q on NM_002238.4) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1024089860, COSV55077090; called by muse, varscan2
- MAP3K1 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV68123021; called by muse, mutect2, varscan2
- MAP3K1 | c.4474del p.Q1492Nfs*12 | Frame Shift Del (DEL) | VAF 28/101 reads (28%) | catalogued as COSV68123025, COSV68127064; called by mutect2, pindel, varscan2
- MAPK8IP3 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51718902; called by muse, mutect2, varscan2
- NDUFS1 | c.1868T>G p.I623R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201634181; called by muse, mutect2
- NLRP5 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as rs199475774, COSV66763391; ClinVar: not provided; called by muse, mutect2, varscan2
- NNT | c.3111G>C p.Q1037H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV52924198; called by muse, mutect2, varscan2
- OR2F1 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 229/445 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67331195; called by muse, mutect2, varscan2
- PNCK | c.414+1G>T p.X138_splice (on ENST00000340888 / NM_001366975.1; = p.X221_splice on NM_001039582.3) | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as COSV61743270; called by muse, mutect2, varscan2
- RAD50 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1351416655, COSV54750154; called by muse, mutect2, varscan2
- SAMD9 | c.2231C>G p.T744S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV66074406; called by muse, mutect2, varscan2
- SEC14L5 | c.1567dup p.H523Pfs*19 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs1436486827; called by pindel, varscan2
- SREBF2 | c.2208+1G>A p.X736_splice | Splice Site (SNP) | VAF 93/237 reads (39%) | catalogued as rs766904764, COSV63330959; called by muse, mutect2, varscan2
- STK25 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57263193; called by muse, mutect2, varscan2
- TRIM71 | c.2460G>T p.M820I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV67470645; called by muse, mutect2, varscan2
- UNC13B | c.1462C>G p.P488A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs542947932, COSV65933775; called by muse, mutect2, varscan2
- ZBTB49 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs141272395; called by muse, mutect2, varscan2
- ZNF416 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs769996734, COSV52183989; called by muse, mutect2, varscan2
- GATA3 | c.1220dup p.P408Afs*99 | Frame Shift Ins (INS) | VAF 32/124 reads (26%) | called by mutect2, pindel, varscan2
- C1QTNF4 | c.876C>T p.D292= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs775566188, COSV56783128; called by muse, mutect2, varscan2
- IGF1R | c.2961C>T p.Y987= | Silent (SNP) | VAF 310/785 reads (39%) | catalogued as rs35449468; called by muse, mutect2, varscan2
- LMBR1 | c.870A>G p.R290= | Silent (SNP) | VAF 77/353 reads (22%) | catalogued as COSV62219513; called by muse, mutect2, varscan2
- STARD8 | c.1437C>T p.R479= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs774544532, COSV52922262, COSV52923517; called by muse, mutect2, varscan2
- THNSL2 | c.603G>A p.P201= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs769791655, COSV59081938; called by muse, mutect2
- TRIP4 | c.999G>A p.R333= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV56030443; called by muse, mutect2, varscan2
- TRO | c.2625G>A p.T875= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1316572829, COSV51500225; called by muse, mutect2, varscan2
- ZNF277 | c.1218C>G p.L406= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs1310152202, COSV62463356; called by muse, mutect2, varscan2
